Somatic mutation profile of tumor specimen 0DT9NK from CCDI case PBCJKS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,537 days).
Specimen 0DT9NK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14c9d824-fd49-4dfd-ac5c-0300686792d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9NF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82b262a1-55c7-4ec2-ae97-d8c9d4c221eb

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, 5'UTR 2, Intron 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 475/954 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FAM184B | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 163/404 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as rs1261300789; called by muse, mutect2, varscan2
- GRK6 | c.1699G>A p.D567N (on ENST00000355472 / NM_001004106.3; = p.A567= on NM_002082.3) | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs748162611, COSV62683367; called by muse, mutect2, varscan2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 474/1031 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- PDGFRA | c.1730C>A p.P577Q | Missense Mutation (SNP) | VAF 345/887 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV57270321, COSV57277054; called by muse, mutect2, varscan2
- PPM1D | c.1280G>A p.W427* | Nonsense Mutation (SNP) | VAF 403/730 reads (55%) | catalogued as COSV59954246; called by muse, mutect2, varscan2
- RFPL4AL1 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 239/1631 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.087); catalogued as rs563804580; called by muse, mutect2, varscan2
- ARFGEF3 | c.1768A>G p.R590G | Missense Mutation (SNP) | VAF 268/702 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CDH18 | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 505/1299 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CREBRF | c.1544T>C p.V515A | Missense Mutation (SNP) | VAF 421/1075 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DCK | c.299C>G p.A100G | Missense Mutation (SNP) | VAF 456/1183 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TLR7 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 574/1364 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- TNXB | c.3872T>C p.I1291T (on ENST00000647633; = p.I1044T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/392 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP2R5A | c.637C>A p.R213= | Silent (SNP) | VAF 263/1681 reads (16%) | catalogued as COSV54818952; called by muse, mutect2, varscan2
- RNF213 | c.7761C>T p.D2587= | Silent (SNP) | VAF 179/614 reads (29%) | catalogued as rs756451900, COSV100301339; called by muse, mutect2, varscan2
- TEDC1 | c.960G>A p.L320= (on ENST00000392523 / NM_001367178.1; = p.L251= on NM_001134875.1) | Silent (SNP) | VAF 83/226 reads (37%) | catalogued as rs1263460901; called by muse, mutect2, varscan2
- UPF2 | c.1743A>G p.R581= | Silent (SNP) | VAF 183/574 reads (32%) | called by muse, mutect2, varscan2
- HLX | c.-18G>A | 5'UTR (SNP) | VAF 44/152 reads (29%) | catalogued as rs1278661112; called by muse, mutect2, varscan2
- MS4A1 | c.574-94C>T | Intron (SNP) | VAF 110/274 reads (40%) | catalogued as rs570869590; called by muse, mutect2, varscan2
- NUBP2 | c.136-26G>A | Intron (SNP) | VAF 111/286 reads (39%) | catalogued as rs778574737; called by muse, mutect2, varscan2
- SCAP | c.-9C>T | 5'UTR (SNP) | VAF 216/500 reads (43%) | catalogued as rs771297313, COSV99652632; called by muse, mutect2, varscan2
- TRIM64B | c.*72C>T | 3'UTR (SNP) | VAF 126/525 reads (24%) | catalogued as rs1247908787; called by muse, mutect2, varscan2
